ALCHEMIST case ALCH-B2LT — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/3dcf945a-1cee-4617-9915-14bcc12d58f8

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 64.9 years (23,700 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2LT-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2LT-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2LT-TTP1-B-1-0-S1: Section location: Top; Percent tumor cells: 62; Percent tumor nuclei: 73; Percent normal cells: 13; Percent necrosis: 20; Percent stromal cells: 5; Percent lymphocyte infiltration: 18; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
